Surgical pathology report (de-identified scan), TCGA case TCGA-06-1800, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-1800-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

TCGA-06-1800

CLINICAL HISTORY

Brain mass.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, left parietal tumor, biopsy

B: Left parietal tumor

PATHOLOGICAL DIAGNOSIS:

A and B Brain, left parietal lobe : Gliosarcoma, MIB-1 : 50%

COMMENT

T1 is a gliosarcoma with biphasic patterns. It is stained positive for GFAP and reticulum. Immunostain for cytokeratin is negative.

Electronically Signed Out

Senior Staff Pathologist

Senior Staff Pathologist

GROSS DESCRIPTION

A.

SPECIMEN: Left parietal tumor.

FIXATIVE: None.

GENERAL: One 0.6 cm tissue,

SECTIONS: A1 A2

B.

SPECIMEN: Left parietal tumor

FIXATIVE: None.

GENERAL: Received is a 2.5 x 1.5 x 0.5 cm. irregular portion of tan-pink
gli-enhancing soft tissue.

MA FINDINGS: The specimens are serially sectioned to reveal homogeneous cut
surfaces.

[page 2 of 2]
SECTIONS: B1-B2 entirely submitted.

TCGA-06-1800

ICD-9(s):
191.9 191.9

Histo Data

Part A: Brain, left parietal tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
H/E x 1	2		

Part B: Left parietal tumor

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
mGFAP-DA x 1	1		
H/E x 1	1		
KeratinSu x 1	1		
MIB1-DA x 1	1		
Retic x 1	1		
H/E x 1	2		

*** End of Report ***

Source: NCI Genomic Data Commons file 14a6e87c-a2a6-45ff-9a6f-a1c28860b7d7 (TCGA-06-1800.09F29D54-F430-4AA8-92FC-137A0B147909.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).